Somatic mutation profile of tumor specimen TCGA-CV-A45Z-01A (aliquot TCGA-CV-A45Z-01A-21D-A25D-08) from TCGA case TCGA-CV-A45Z, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G3; Age at diagnosis: 75.0 years (27,397 days).
Specimen TCGA-CV-A45Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0bb53d0-0aed-4730-b1bd-85d1b4414ce2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A45Z-10A (Blood Derived Normal), aliquot TCGA-CV-A45Z-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed93a591-1c08-47cd-be6d-dac2b7519c9c

The open-access MAF lists 725 somatic variants for this specimen: 553 protein-altering or splice-affecting, 159 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 488, Silent 159, Nonsense Mutation 26, Splice Site 19, Frame Shift Del 14, RNA 6, Intron 4, Frame Shift Ins 2, 5'UTR 2, Splice Region 1, 3'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4416G>T p.W1472C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52117493; called by muse, mutect2, varscan2
- H3C2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV52517971, COSV52518546; called by muse, mutect2, varscan2
- KCNQ1 | c.536G>C p.G179A | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs76737438; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PGAM2 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750422335, COSV99803949; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A4GNT | c.131C>G p.A44G | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99368008; called by muse, mutect2
- AADACL4 | c.703T>G p.F235V | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV100879513; called by muse, mutect2, varscan2
- ABI2 | c.655C>T p.R219C (on ENST00000295851 / NM_001375719.1; = p.R213C on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs761783921, COSV99652326; called by muse, mutect2, varscan2
- AC131160.1 | c.508A>T p.T170S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.23); catalogued as COSV100226400; called by muse, mutect2, varscan2
- ACOT6 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV101142034; called by muse, mutect2, varscan2
- ACTN2 | c.2497G>C p.A833P | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.816); catalogued as COSV100857079, COSV63975491, COSV63975814; called by muse, mutect2, varscan2
- ACVR1B | c.862G>T p.G288W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57774982, COSV57781449; called by muse, mutect2, varscan2
- ADAD1 | c.530-1G>T p.X177_splice | Splice Site (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99636385; called by muse, mutect2, varscan2
- ADGRA2 | c.2268C>A p.S756R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.359); catalogued as rs752796811, COSV99605167; called by muse, mutect2, varscan2
- ADGRB3 | c.3288-1G>T p.X1096_splice | Splice Site (SNP) | VAF 11/107 reads (10%) | catalogued as COSV53260256, COSV99487096; called by muse, mutect2
- ADGRG4 | c.1837C>A p.P613T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs779183300; called by muse, mutect2
- ADGRL3 | c.415G>T p.A139S (on ENST00000506720 / NM_001322402.2; = p.A71S on NM_015236.6) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.824); catalogued as rs1560889962, COSV101547414; called by muse, mutect2, varscan2
- ADGRV1 | c.2429T>C p.L810P | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101316638; called by muse, mutect2, varscan2
- ADGRV1 | c.3113A>C p.Y1038S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101316639; called by muse, mutect2, varscan2
- ADRA1B | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV100140084; called by muse, mutect2
- AGT | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.469); catalogued as COSV100794497; called by muse, mutect2, varscan2
- AKAP11 | c.4880A>G p.Y1627C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1159584561, COSV99214421; called by muse, mutect2, varscan2
- AKR1B15 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV101423412; called by muse, mutect2
- AL592490.1 | c.2153G>C p.G718A | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101308299; called by muse, mutect2, varscan2
- AMDHD1 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs1475416396, COSV99900549; called by muse, mutect2, varscan2
- AMPH | c.1158+2T>C p.X386_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100343881; called by muse, mutect2, varscan2
- AMY2B | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100796533; called by muse, mutect2, varscan2
- ANKFN1 | c.280A>G p.N94D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs1407250561, COSV100594296; called by muse, mutect2, varscan2
- ANKRD17 | c.520A>G p.R174G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); catalogued as COSV100430061; called by muse, mutect2, varscan2
- ANKRD37 | c.315G>C p.W105C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99249385; called by muse, mutect2
- ANXA6 | c.1171A>G p.T391A | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.02); catalogued as COSV100637127; called by muse, mutect2, varscan2
- APCS | c.648C>G p.I216M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV99661543; called by muse, mutect2, varscan2
- APOB | c.8057G>T p.W2686L | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as COSV51934567, COSV99268469; called by muse, mutect2
- APOB | c.4771T>A p.F1591I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.391); catalogued as COSV99268472; called by muse, mutect2, varscan2
- APOBEC3D | c.639C>G p.F213L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99329224; called by muse, mutect2, varscan2
- ARFGEF1 | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99145170; called by muse, mutect2
- ARL5B | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV101040413, COSV66011333; called by muse, mutect2
- ARSK | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV101187598; called by muse, mutect2, varscan2
- ART4 | c.788G>C p.R263T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV99967011; called by muse, mutect2
- ASB1 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99223506; called by muse, mutect2
- ASCC3 | c.4270A>G p.I1424V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV100976981; called by muse, mutect2, varscan2
- ASIC3 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1184860869, COSV99875120; called by muse, mutect2
- ASTN1 | c.2672G>T p.G891V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100707811; called by muse, mutect2
- ASXL3 | c.3241A>G p.S1081G | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99326879; called by muse, mutect2, varscan2
- ATP10B | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100469864; called by muse, mutect2
- ATP1A3 | c.1814C>T p.A605V (on ENST00000545399 / NM_001256214.2; = p.A592V on NM_152296.5) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57488340; called by muse, mutect2, varscan2
- ATP2C1 | c.782G>T p.S261I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60763467; called by mutect2, varscan2
- ATXN2 | c.2173C>T p.P725S (on ENST00000550104; = p.P565S on NM_002973.4) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.068); catalogued as COSV101112919; called by muse, mutect2
- B3GNT7 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs780744252, COSV99806047; called by muse, mutect2, varscan2
- B4GALT2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs753370693, COSV58846235; called by muse, mutect2, varscan2
- BAIAP2 | c.598A>C p.K200Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV100348955; called by muse, mutect2
- BDKRB1 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.06); catalogued as COSV99388057; called by muse, mutect2, varscan2
- BEND7 | c.711C>A p.D237E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.995); catalogued as rs765934614, COSV100347093, COSV61990366; called by muse, mutect2, varscan2
- BICC1 | c.1549C>A p.L517I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV99570978; called by muse, mutect2
- BIVM-ERCC5 | c.688A>G p.M230V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.11); catalogued as COSV99959143; called by muse, mutect2
- BMPER | c.1932G>C p.K644N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99780718; called by muse, mutect2
- BPIFA1 | c.519C>G p.I173M | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV100845664; called by muse, mutect2, varscan2
- BRCA2 | c.9367A>G p.S3123G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs80359208, COSV101204684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTNL9 | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV100576295; called by muse, mutect2, varscan2
- C10orf53 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV100935092; called by muse, mutect2, varscan2
- C10orf71 | c.1961C>G p.P654R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as rs910915074, COSV100110712; called by muse, mutect2, varscan2
- C1QL2 | c.817A>G p.N273D | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99733384; called by muse, mutect2
- C6orf58 | c.302-1G>T p.X101_splice | Splice Site (SNP) | VAF 11/87 reads (13%) | catalogued as COSV100315078; called by muse, mutect2, varscan2
- C8B | c.951C>A p.F317L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100980934; called by muse, mutect2, varscan2
- CABCOCO1 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748248447, COSV100358115; called by muse, mutect2, varscan2
- CACNA1D | c.4660G>T p.V1554F (on ENST00000350061 / NM_001128840.3; = p.V1574F on NM_000720.4) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99860315; called by muse, mutect2, varscan2
- CASS4 | c.215C>A p.T72K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.145); catalogued as COSV100824972, COSV64386145; called by muse, varscan2
- CCDC15 | c.2703del p.N902Tfs*47 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | catalogued as COSV61083331; called by pindel, varscan2
- CCDC85A | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101339582; called by muse, mutect2, varscan2
- CCR4 | c.544C>A p.R182S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.026); catalogued as COSV100447546; called by muse, mutect2, varscan2
- CCSER1 | c.216T>A p.H72Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV100396868; called by muse, mutect2, varscan2
- CD163L1 | c.1033G>C p.G345R | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.429); catalogued as rs192198441, COSV100550747, COSV58023997; called by mutect2, varscan2
- CD209 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV52651651, COSV99214509; called by muse, mutect2, varscan2
- CD248 | c.1201A>C p.T401P | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100256783; called by muse, mutect2
- CD93 | c.1265G>C p.G422A | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.247); catalogued as COSV99849660; called by muse, mutect2, varscan2
- CDC23 | c.713A>T p.Y238F | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1395014261, COSV101203172; called by muse, mutect2, varscan2
- CDC26 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100951789; called by muse, mutect2
- CDH17 | c.1786C>A p.L596M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.949); catalogued as COSV99217034; called by muse, mutect2, varscan2
- CDH7 | c.475A>T p.T159S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100543339; called by muse, mutect2
- CDH8 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV100184417; called by muse, mutect2, varscan2
- CDK8 | c.1230del p.T411Lfs*8 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | catalogued as COSV67423335; called by mutect2, pindel
- CDR1 | c.555G>T p.W185C | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV100983465; called by muse, mutect2, varscan2
- CDX4 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as rs776034454, COSV100999162; called by muse, mutect2
- CEP68 | c.819C>A p.Y273* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as COSV99561335; called by muse, varscan2
- CFAP47 | c.4692-2A>T p.X1564_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100545753; called by muse, mutect2
- CFH | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661677; called by muse, mutect2
- CFHR5 | c.1249T>A p.C417S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99889863; called by muse, mutect2
- CHD4 | c.4063G>A p.V1355M (on ENST00000357008 / NM_001363606.2; = p.V1368M on NM_001273.5) | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs1290450080, COSV100539379; called by muse, mutect2, varscan2
- CHSY3 | c.1209C>A p.Y403* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100520098; called by muse, mutect2, varscan2
- CHSY3 | c.2555G>T p.G852V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100520099; called by muse, mutect2, varscan2
- CLASP2 | c.3719A>G p.Y1240C (on ENST00000359576; = p.Y1239C on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs570365071, COSV100224484; called by mutect2, varscan2
- CLTB | c.36G>T p.E12D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.973); catalogued as COSV100125166; called by muse, mutect2, varscan2
- CLU | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV100324259, COSV100324464; called by muse, mutect2, varscan2
- CNKSR2 | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99670009; called by muse, mutect2, varscan2
- COBLL1 | c.423G>T p.L141F (on ENST00000392717; = p.L103F on NM_014900.5) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99528792; called by muse, mutect2, varscan2
- COL10A1 | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as COSV99684510; called by muse, mutect2, varscan2
- COL11A2 | c.3319C>A p.P1107T (on ENST00000341947 / NM_080680.3; = p.P1000T on NM_080679.2) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.34); catalogued as COSV100554609; called by muse, mutect2
- COL21A1 | c.1510T>G p.Y504D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); catalogued as rs1187494717, COSV99780469; called by muse, mutect2, varscan2
- COL4A3 | c.4465A>T p.T1489S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV101170593; called by muse, mutect2
- COL6A6 | c.827A>T p.E276V | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV100651022; called by muse, mutect2, varscan2
- COL7A1 | c.6692C>T p.P2231L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as COSV100097865; called by muse, mutect2, varscan2
- CORIN | c.1099G>T p.D367Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150957535, COSV99904561; called by mutect2, varscan2
- CPEB2 | c.2755A>G p.K919E | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99470745; called by muse, mutect2, varscan2
- CREBZF | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99476498; called by muse, mutect2, varscan2
- CSMD1 | c.8316G>T p.Q2772H (on ENST00000520002; = p.Q2771H on NM_033225.6) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as COSV100154530; called by muse, mutect2, varscan2
- CSMD3 | c.9380G>A p.R3127Q (on ENST00000297405 / NM_001363185.1; = p.R2958Q on NM_052900.3) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.888); catalogued as rs752773200, COSV52165293, COSV52249136; called by muse, mutect2, varscan2
- CTIF | c.1244G>C p.R415P | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.531); catalogued as COSV56483906, COSV56485004; called by mutect2, varscan2
- CTNNA3 | c.2011G>T p.E671* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as COSV101041232, COSV65523703; called by muse, mutect2, varscan2
- CTNND2 | c.1345C>A p.H449N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV100481543; called by muse, mutect2, varscan2
- CTTNBP2 | c.4613G>T p.C1538F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99354972; called by muse, mutect2, varscan2
- CUBN | c.7054C>T p.H2352Y | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100913665; called by muse, mutect2
- CXXC4 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV101182331; called by muse, mutect2, varscan2
- CXorf21 | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.184); catalogued as COSV100973370; called by muse, mutect2, varscan2
- CYP2B6 | c.211G>T p.G71* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100137830, COSV57843205; called by mutect2, varscan2
- CYP7B1 | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746851278, COSV100043136; called by muse, mutect2, varscan2
- DAAM2 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1446169943, COSV99227308; called by muse, mutect2
- DCAF12L2 | c.806C>A p.A269D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100758892; called by muse, mutect2
- DCC | c.2557G>T p.V853L | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.109); catalogued as COSV100503387; called by muse, mutect2
- DDX11 | c.1220G>T p.S407I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99300376; called by muse, mutect2
- DDX59 | c.1045A>G p.I349V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.03); catalogued as COSV100494731; called by muse, mutect2, varscan2
- DDX60 | c.1873G>T p.D625Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV101190726, COSV67099678; called by muse, mutect2, varscan2
- DENND2C | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs756849345, COSV101283981; called by muse, mutect2, varscan2
- DGKB | c.2125G>C p.D709H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99343901; called by muse, mutect2
- DGKK | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV101053237; called by muse, mutect2
- DIP2A | c.2875G>T p.V959F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100596394; called by muse, mutect2
- DIXDC1 | c.1384C>A p.L462I (on ENST00000440460 / NM_001037954.4; = p.L251I on NM_033425.4) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100180484; called by muse, mutect2, varscan2
- DMRTC2 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV99523499; called by muse, mutect2
- DMXL2 | c.875C>A p.A292D | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV99198717; called by muse, mutect2, varscan2
- DNAH3 | c.1251G>T p.E417D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99771035; called by muse, mutect2
- DNAH9 | c.7882A>G p.S2628G | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs983318055, COSV99308504; called by muse, mutect2, varscan2
- DNAJC12 | c.303G>T p.M101I | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV99830765; called by muse, mutect2
- DNASE1L3 | c.308C>A p.A103D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100568866; called by muse, mutect2
- DNMT1 | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as COSV100531752, COSV100533157; called by muse, mutect2
- DPP10 | c.2011G>T p.G671* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100072508; called by muse, varscan2
- DPYSL5 | c.791-1G>T p.X264_splice | Splice Site (SNP) | VAF 22/126 reads (17%) | catalogued as COSV99982866; called by muse, mutect2
- DSEL | c.3284G>A p.R1095K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV59495273; called by muse, mutect2, varscan2
- DSP | c.2374A>C p.T792P | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.844); catalogued as COSV101131836; called by muse, mutect2, varscan2
- DSTYK | c.2400G>T p.K800N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100904748; called by muse, mutect2, varscan2
- DTWD1 | c.397A>C p.K133Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99233798; called by mutect2, varscan2
- EMILIN2 | c.2761G>T p.G921W | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.87); catalogued as COSV99598989; called by muse, mutect2
- EPB41L2 | c.1778G>A p.R593K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV100441487; called by muse, mutect2, varscan2
- EPB41L5 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.318); catalogued as rs1190522916, COSV99759305; called by muse, mutect2
- EPHA7 | c.1526C>G p.T509R | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100994422; called by muse, mutect2, varscan2
- EPHA7 | c.1220C>A p.A407D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV100994424; called by muse, mutect2, varscan2
- EPPK1 | c.5356G>T p.V1786L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs368495019, COSV101599975; called by muse, mutect2, varscan2
- ERCC3 | c.1738A>G p.I580V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53428114; called by muse, mutect2, varscan2
- EXOC3 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV100155681; called by muse, mutect2
- EXPH5 | c.4628G>T p.R1543I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.8); catalogued as COSV56208826; called by muse, mutect2, varscan2
- EYS | c.1631A>C p.E544A | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV100677224; called by muse, mutect2
- FAAH2 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV100887481; called by muse, mutect2, varscan2
- FAAP100 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100585626; called by muse, mutect2, varscan2
- FAM107B | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.024); catalogued as COSV99474521; called by muse, mutect2, varscan2
- FAM122A | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99597943, COSV99599929; called by muse, mutect2, varscan2
- FAM135B | c.3866G>T p.R1289L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52714222, COSV99428250; called by muse, mutect2, varscan2
- FAM155A | c.656C>A p.S219* | Nonsense Mutation (SNP) | VAF 10/81 reads (12%) | catalogued as COSV101030740, COSV65590911; called by muse, mutect2, varscan2
- FAM170A | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (1); catalogued as COSV100089389; called by muse, mutect2
- FAM47C | c.104A>C p.H35P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100792982; called by muse, mutect2, varscan2
- FANCD2OS | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV99812718; called by muse, mutect2, varscan2
- FAT3 | c.231G>C p.W77C | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53085490, COSV99971708; called by muse, mutect2
- FAT3 | c.4906C>G p.Q1636E | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.231); catalogued as COSV99971709; called by muse, mutect2, varscan2
- FAT3 | c.7031G>T p.G2344V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99971710; called by muse, mutect2, varscan2
- FBXO21 | c.632A>G p.D211G | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV100401888; called by muse, mutect2, varscan2
- FCRL5 | c.380C>A p.A127E | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.449); catalogued as COSV100708750, COSV62519780; called by muse, mutect2, varscan2
- FGF12 | c.731A>T p.*244Lext*53 (on ENST00000454309 / NM_021032.5; = p.*182Lext*53 on NM_004113.6) | Nonstop Mutation (SNP) | VAF 12/126 reads (10%) | catalogued as COSV99284132; called by muse, mutect2
- FMO1 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.249); catalogued as COSV100707977, COSV100708035; called by muse, mutect2, varscan2
- FOXJ2 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs143592450; called by muse, mutect2
- FRAS1 | c.10154A>G p.Y3385C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV99356203; called by muse, mutect2, varscan2
- FREM1 | c.3365C>A p.T1122K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV101085613; called by muse, mutect2, varscan2
- FREM1 | c.737G>T p.R246L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV101085614, COSV104428360; called by muse, mutect2, varscan2
- FREM2 | c.8041G>C p.V2681L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as rs367698077, COSV99751309; called by muse, mutect2, varscan2
- FREM2 | c.8611C>A p.L2871I | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.646); catalogued as rs1459726077, COSV54843916, COSV99751311; called by muse, mutect2, varscan2
- FRMPD2 | c.3154G>T p.E1052* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as COSV100564261; called by muse, mutect2, varscan2
- FSTL5 | c.925A>T p.T309S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV100061930; called by muse, mutect2, varscan2
- FXR1 | c.1540G>C p.D514H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV99976299, COSV99976713; called by muse, mutect2, varscan2
- FZD1 | c.1409G>T p.G470V | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99842810; called by muse, mutect2
- G6PC2 | c.664T>A p.Y222N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99960954; called by muse, mutect2, varscan2
- GABRB1 | c.1360C>G p.R454G | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54992094, COSV54999936; called by muse, mutect2
- GABRG1 | c.1376G>T p.W459L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99778469; called by muse, mutect2, varscan2
- GABRG3 | c.138C>A p.D46E | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.103); catalogued as COSV61526521, COSV61529950; called by muse, mutect2, varscan2
- GBP6 | c.1662G>T p.K554N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100969713; called by muse, mutect2, varscan2
- GCM1 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99452690; called by muse, mutect2, varscan2
- GDF6 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV99748649; called by muse, mutect2
- GDPD5 | c.1763del p.G588Afs*13 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as COSV61130120; called by mutect2, pindel, varscan2
- GFRAL | c.618C>A p.H206Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100476087; called by muse, mutect2, varscan2
- GGA1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs186081433, COSV100289925; called by muse, mutect2, varscan2
- GJD2 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV51747534, COSV99290937; called by muse, mutect2
- GLB1L3 | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV101111136; called by muse, mutect2, varscan2
- GLI3 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV101229790; called by muse, mutect2
- GLYATL1 | c.724G>T p.G242C (on ENST00000317391 / NM_001354699.1; = p.G273C on NM_080661.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100265591; called by muse, mutect2, varscan2
- GLYATL2 | c.518C>G p.A173G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV99780571; called by muse, mutect2
- GOLGA1 | c.702G>T p.Q234H | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV101002617, COSV65229640; called by muse, mutect2
- GPATCH2 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100861874, COSV65132637; called by muse, mutect2, varscan2
- GPC5 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV100996232; called by muse, mutect2, varscan2
- GPR158 | c.3277C>A p.P1093T | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV100894384; called by muse, mutect2, varscan2
- GPR37 | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.99); catalogued as COSV100391193; called by muse, mutect2, varscan2
- GREM2 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100548050; called by muse, mutect2
- GRIA3 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99992032; called by muse, mutect2, varscan2
- GRIK4 | c.1016A>T p.Q339L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV101483839; called by muse, mutect2, varscan2
- GRIK5 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99491443; called by muse, mutect2, varscan2
- GUCY1A1 | c.1496C>G p.P499R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99638821; called by muse, mutect2, varscan2
- H2AC1 | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as COSV99219594; called by muse, mutect2, varscan2
- H2BC10 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as COSV100010382; called by muse, mutect2, varscan2
- HAO1 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV101113348; called by muse, mutect2, varscan2
- HCN1 | c.1193A>T p.Q398L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV100302618; called by muse, mutect2
- HDAC6 | c.1277G>T p.C426F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.706); catalogued as COSV100491305, COSV61929594; called by muse, mutect2, varscan2
- HEPHL1 | c.2905G>A p.A969T | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100244482; called by muse, mutect2
- HERC1 | c.9527G>C p.R3176T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101497010; called by muse, mutect2, varscan2
- HERC2 | c.4415C>G p.T1472R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.279); catalogued as COSV99877294; called by muse, mutect2, varscan2
- HNF4A | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100291776; called by muse, mutect2, varscan2
- HNRNPH1 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271006; called by muse, mutect2, varscan2
- HTR2A | c.923G>C p.G308A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV101096887; called by muse, mutect2, varscan2
- HTR2C | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.999); catalogued as COSV99351298; called by muse, mutect2, varscan2
- HTR5A | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | catalogued as COSV99839982, COSV99840032; called by muse, mutect2
- IGF2BP1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV99289176; called by muse, mutect2
- IGHMBP2 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99662649; called by muse, mutect2
- IL1RAPL2 | c.1613G>T p.G538V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100782133; called by muse, mutect2, varscan2
- IL3RA | c.821C>G p.A274G | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.487); catalogued as COSV100452411; called by muse, mutect2, varscan2
- IMPG1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV64058703; called by muse, mutect2, varscan2
- INSR | c.3544A>G p.R1182G | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100253706; called by muse, mutect2, varscan2
- IQGAP1 | c.4531G>T p.A1511S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV51585002, COSV99185407; called by muse, mutect2
- IRF1 | c.365-2A>G p.X122_splice | Splice Site (SNP) | VAF 15/114 reads (13%) | catalogued as COSV99810781; called by muse, mutect2, varscan2
- KCNA4 | c.95G>T p.R32M | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100069316; called by muse, mutect2, varscan2
- KCNC2 | c.423G>T p.W141C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100130019; called by muse, mutect2
- KCNC2 | c.422G>T p.W141L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as COSV100130021; called by muse, mutect2
- KCNH2 | c.2042G>C p.R681P | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100061231, COSV51133689, COSV51228014; called by muse, varscan2
- KCNT2 | c.1825G>T p.A609S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99657156; called by muse, mutect2, varscan2
- KCNV1 | c.1082C>G p.S361* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV52086584, COSV99819484; called by muse, mutect2, varscan2
- KIAA0100 | c.2720G>T p.R907I | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101197272; called by muse, mutect2
- KIAA1614 | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100851370; called by muse, mutect2, varscan2
- KIDINS220 | c.3256G>C p.E1086Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as COSV99875093, COSV99876134, COSV99876569; called by muse, mutect2, varscan2
- KIF16B | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734988; called by muse, mutect2, varscan2
- KIF5C | c.2369C>G p.T790R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1331114011, COSV101276218; called by muse, mutect2
- KL | c.2869G>A p.E957K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV101199233; called by muse, mutect2, varscan2
- KLHL1 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV100918251; called by muse, mutect2, varscan2
- KRT6A | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100417280; called by muse, mutect2, varscan2
- KRTAP13-2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs766217527, COSV67761878; called by muse, mutect2, varscan2
- KRTAP9-2 | c.491G>T p.C164F | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV100893259; called by muse, mutect2
- LARP4B | c.1695G>T p.R565S | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs201148474, COSV100295743; called by muse, mutect2, varscan2
- LBH | c.218T>A p.V73E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101257817; called by muse, mutect2
- LBH | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101257818; called by muse, mutect2
- LDB3 | c.1829G>T p.C610F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99555964; called by muse, mutect2, varscan2
- LHCGR | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99684306; called by muse, mutect2, varscan2
- LHX9 | c.643T>G p.Y215D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV100436103; called by muse, mutect2, varscan2
- LIN28B | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100559132; called by muse, mutect2, varscan2
- LLCFC1 | c.437A>C p.Q146P (on ENST00000458732; = p.Q115P on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100787329; called by muse, mutect2, varscan2
- LNPK | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99770517; called by muse, mutect2
- LRP1B | c.11387G>T p.C3796F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV101261754; called by muse, mutect2, varscan2
- LRRC6 | c.1227-2A>T p.X409_splice | Splice Site (SNP) | VAF 17/76 reads (22%) | catalogued as COSV99138711; called by muse, mutect2, varscan2
- LRRC6 | c.178+2T>A p.X60_splice | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99138712; called by mutect2, varscan2
- LRRC6 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV99138716; called by muse, mutect2, varscan2
- LRRIQ3 | c.173C>G p.S58* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100599549; called by muse, mutect2, varscan2
- LRRTM3 | c.482G>A p.S161N | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.07); catalogued as COSV100791941; called by muse, mutect2, varscan2
- LRTM2 | c.611G>A p.C204Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99766665; called by muse, mutect2, varscan2
- LTBP1 | c.2680G>C p.V894L (on ENST00000404816 / NM_206943.4; = p.V568L on NM_000627.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.779); catalogued as COSV100618011; called by mutect2, varscan2
- LZTFL1 | c.561A>T p.K187N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99944937; called by muse, mutect2, varscan2
- MACF1 | c.3392T>G p.L1131R | Missense Mutation (SNP) | VAF 5/65 reads (8%) | catalogued as COSV100486792; called by muse, mutect2
- MACROD2 | c.919G>T p.A307S (on ENST00000642719; = p.A279S on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV99444848; called by mutect2, varscan2
- MAEL | c.918C>G p.I306M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100901998, COSV63305234; called by muse, mutect2, varscan2
- MAML1 | c.1016C>A p.P339H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV99483052, COSV99483470; called by mutect2, varscan2
- MAML2 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV101594210; called by muse, mutect2
- MAP3K13 | c.1234G>C p.A412P | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV99408109; called by muse, mutect2, varscan2
- MAPK7 | c.2090G>T p.G697V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100219111; called by muse, mutect2, varscan2
- MARCHF8 | c.362G>C p.R121P | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100166019, COSV100166115, COSV60572107; called by muse, mutect2, varscan2
- MARCKS | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100893096, COSV100893099; called by muse, mutect2, varscan2
- MBD5 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV101290285; called by muse, mutect2
- MCF2 | c.2707A>G p.T903A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100645225; called by muse, mutect2, varscan2
- MDGA2 | c.1397C>T p.P466L (on ENST00000399232 / NM_001113498.2; = p.P168L on NM_182830.4) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs1001049845, COSV62077688; called by muse, mutect2
- MIER3 | c.1054G>C p.D352H (on ENST00000381199 / NM_001297599.2; = p.D351H on NM_152622.4) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101167699; called by muse, mutect2, varscan2
- MKI67 | c.479A>G p.K160R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as COSV100897045; called by muse, mutect2, varscan2
- MLPH | c.1658A>G p.N553S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV99222782; called by muse, mutect2
- MMP27 | c.1249C>G p.H417D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99498743; called by muse, mutect2, varscan2
- MRPL20 | c.201C>G p.L67= | Splice Region (SNP) | VAF 4/67 reads (6%) | catalogued as COSV100785052; called by muse, mutect2
- MSANTD3 | c.184G>C p.V62L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.962); catalogued as COSV100615060, COSV58493970; called by muse, mutect2, varscan2
- MTARC1 | c.809G>T p.C270F | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375617476; called by muse, mutect2, varscan2
- MTMR12 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99374146; called by muse, mutect2, varscan2
- MTUS1 | c.1152G>C p.K384N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100030158; called by muse, mutect2, varscan2
- MUC16 | c.4372del p.A1458Qfs*4 | Frame Shift Del (DEL) | VAF 20/106 reads (19%) | catalogued as COSV67474726; called by mutect2, pindel, varscan2
- MUC5B | c.7786C>A p.P2596T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1564941956, COSV101500853, COSV71592350; called by muse, mutect2, varscan2
- MYH4 | c.2822C>G p.T941R | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99702417; called by muse, mutect2
- MYH8 | c.376G>C p.V126L | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV101238480, COSV101238912; called by muse, mutect2, varscan2
- MYO10 | c.5805C>A p.N1935K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV99946424; called by muse, mutect2, varscan2
- MYO1G | c.607G>C p.A203P | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.465); catalogued as rs761378235, COSV99349194; called by muse, mutect2, varscan2
- MYO1H | c.2943A>T p.K981N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99949470; called by muse, mutect2, varscan2
- MYOM2 | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs144235879; called by muse, mutect2
- NALCN | c.4460C>A p.T1487K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99218184; called by muse, mutect2
- NBEA | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100084782; called by muse, mutect2
- NBEA | c.2959C>A p.L987I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.967); catalogued as COSV100084783; called by muse, mutect2, varscan2
- NCAM2 | c.1006A>T p.R336* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99525626; called by muse, varscan2
- NCAM2 | c.1851C>A p.D617E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53066597, COSV99525628; called by mutect2, varscan2
- NETO2 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs144054886; called by muse, mutect2, varscan2
- NEURL2 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99510177; called by muse, mutect2, varscan2
- NEUROD6 | c.736A>T p.S246C | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV99774223; called by muse, mutect2
- NIPA2 | c.719T>A p.L240Q | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100488841; called by muse, mutect2
- NISCH | c.4169A>C p.Y1390S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100402360; called by muse, mutect2, varscan2
- NLRP14 | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV100205478; called by muse, mutect2
- NLRP9 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 36/385 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.716); catalogued as COSV100243548; called by muse, mutect2
- NNT | c.2245G>A p.G749S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99239680; called by muse, mutect2, varscan2
- NPFFR2 | c.1229A>T p.Q410L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV100441385; called by muse, mutect2, varscan2
- NPHP1 | c.455C>A p.S152* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100338560; called by mutect2, varscan2
- NRXN1 | c.4035C>A p.S1345R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs1039999157, COSV100640767; called by muse, mutect2
- NRXN1 | c.2110G>T p.G704* | Nonsense Mutation (SNP) | VAF 34/169 reads (20%) | catalogued as COSV100457176; called by muse, mutect2, varscan2
- NSD1 | c.1801A>T p.K601* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as CM1513370, COSV100729877; called by muse, mutect2, varscan2
- NUP37 | c.424A>C p.S142R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV99195874; called by muse, mutect2, varscan2
- NUP62 | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.258); catalogued as COSV61312502; called by muse, mutect2, varscan2
- OFD1 | c.382-2A>T p.X128_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as CS085071, COSV100407187; called by muse, mutect2
- OOSP2 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV99613664; called by muse, mutect2, varscan2
- OR10J3 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs369650761; called by muse, mutect2, varscan2
- OR1C1 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101376291, COSV68715583; called by muse, mutect2, varscan2
- OR2AE1 | c.935G>T p.C312F | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs755904424, COSV100318433; called by muse, mutect2, varscan2
- OR2B11 | c.562G>T p.V188L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100276740; called by muse, mutect2, varscan2
- OR2F2 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101283863; called by muse, mutect2
- OR2M2 | c.1019T>C p.L340P | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0.01); catalogued as rs1398774282, COSV100677325; called by muse, mutect2
- OR2T11 | c.760T>A p.Y254N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100424987; called by muse, mutect2, varscan2
- OR4A15 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV59034843; called by muse, mutect2
- OR4A16 | c.754T>C p.C252R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100125423; called by muse, mutect2, varscan2
- OR4A5 | c.67A>C p.K23Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV100157329; called by muse, mutect2, varscan2
- OR4C12 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.068); catalogued as COSV100078720; called by muse, mutect2, varscan2
- OR4C6 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.007); catalogued as rs367721616, COSV100051885, COSV58605413; called by muse, varscan2
- OR4C6 | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV100051886; called by muse, varscan2
- OR4F6 | c.445T>C p.W149R | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV100187014; called by muse, mutect2
- OR4M1 | c.571A>G p.N191D | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100271548; called by muse, mutect2, varscan2
- OR4P4 | c.887T>A p.M296K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV58920576; called by muse, mutect2, varscan2
- OR4Q3 | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100057440; called by muse, mutect2
- OR52B6 | c.351C>G p.C117W | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100798555, COSV61447995; called by muse, mutect2, varscan2
- OR52N1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100398745; called by muse, mutect2
- OR5D16 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65723119; called by muse, mutect2
- OR5D18 | c.650C>A p.T217K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs757403859, COSV100450663, COSV61738993; called by muse, mutect2, varscan2
- OR5H14 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 21/259 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101454328; called by muse, mutect2
- OR5T3 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV100282961; called by muse, mutect2, varscan2
- OR5W2 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV100747767; called by muse, mutect2, varscan2
- OR9A2 | c.73A>G p.I25V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100628295; called by muse, mutect2, varscan2
- OSBPL8 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99675694; called by muse, mutect2, varscan2
- OTUD6A | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs757064205, COSV100611099; called by muse, varscan2
- PABPC3 | c.143C>G p.T48S | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.303); catalogued as COSV99880173; called by muse, mutect2
- PABPC5 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs1457943911, COSV100442716, COSV57038958; called by muse, mutect2
- PANX2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1319181499, COSV99348715; called by muse, mutect2, varscan2
- PCDH10 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52092575; called by muse, mutect2
- PCDH11X | c.2240A>C p.H747P | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100011552; called by muse, mutect2, varscan2
- PCDH15 | c.3686G>A p.G1229E | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777169552, COSV100228486; called by mutect2, varscan2
- PCDH15 | c.2798G>C p.G933A | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.98); catalogued as COSV100228491; called by muse, mutect2
- PCDH17 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV100932118; called by muse, mutect2
- PCDH17 | c.1408C>A p.P470T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100932119; called by muse, mutect2, varscan2
- PCDH17 | c.3153A>T p.K1051N | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100932120; called by muse, mutect2, varscan2
- PCDH18 | c.2362G>A p.G788R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.383); catalogued as COSV100787540, COSV99049248; called by muse, mutect2, varscan2
- PCDHB12 | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1554286627, COSV99507932; called by muse, mutect2
- PCDHB13 | c.2036C>A p.T679N | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99507936; called by muse, mutect2, varscan2
- PCDHB5 | c.391C>G p.P131A | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV50648318, COSV99169681; called by muse, mutect2, varscan2
- PCDHB7 | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782717110, COSV50753777, COSV50773647; called by muse, mutect2, varscan2
- PCDHB8 | c.1876C>G p.R626G | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99177489; called by muse, mutect2, varscan2
- PCDHGA8 | c.823G>C p.G275R | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV99548240; called by muse, mutect2
- PCGF3 | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100745525; called by muse, mutect2, varscan2
- PCLO | c.13243G>T p.D4415Y | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100438717; called by muse, mutect2
- PCLO | c.10149G>C p.Q3383H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV100438720; called by muse, mutect2, varscan2
- PCLO | c.5530C>A p.Q1844K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100438722; called by muse, mutect2, varscan2
- PCLO | c.2705C>T p.S902L | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV100438725, COSV61613337; called by muse, mutect2, varscan2
- PCLO | c.2414G>T p.S805I | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV100438727; called by muse, mutect2
- PDAP1 | c.47A>T p.Q16L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV99769262; called by muse, mutect2, varscan2
- PDGFRA | c.2069G>T p.R690M | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1344375373, COSV99957863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDHA2 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99757342; called by muse, mutect2, varscan2
- PDHA2 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs1224480602, COSV99757343; called by muse, mutect2, varscan2
- PDZRN3 | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99732423; called by muse, mutect2, varscan2
- PDZRN4 | c.2369C>A p.S790* (on ENST00000402685 / NM_001164595.2; = p.S532* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 13/115 reads (11%) | catalogued as COSV100115621; called by muse, mutect2, varscan2
- PEX1 | c.265G>T p.G89W | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99952442; called by muse, mutect2, varscan2
- PGLYRP2 | c.901A>G p.S301G | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99484331; called by muse, mutect2
- PHF21B | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.421); catalogued as rs1161871208, COSV100504001, COSV100504117; called by muse, mutect2
- PKD1 | c.3824G>T p.G1275V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs577536178, CD1110568, COSV99239195; called by muse, mutect2, varscan2
- PKHD1 | c.3227G>T p.R1076M | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.819); catalogued as COSV100584781; called by muse, mutect2
- PKLR | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV61360849; called by muse, mutect2, varscan2
- PLA2G4C | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.017); catalogued as COSV100844075; called by muse, mutect2
- PLCE1 | c.3749A>T p.E1250V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV99597540; called by muse, mutect2, varscan2
- PLCL1 | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101407318; called by muse, mutect2, varscan2
- PLCXD3 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100125541, COSV100126017, COSV100126525; called by muse, mutect2, varscan2
- PLEKHA5 | c.1649T>C p.I550T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV100164830; called by muse, mutect2, varscan2
- PLPPR4 | c.1842C>A p.D614E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as COSV100926849, COSV100926962; called by muse, mutect2, varscan2
- PLSCR2 | c.863T>C p.I288T (on ENST00000497985 / NM_001199978.1; = p.I215T on NM_020359.2) | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs550593565, COSV100367744; called by muse, mutect2, varscan2
- PLXNA1 | c.5351G>T p.C1784F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99304247; called by muse, mutect2, varscan2
- PODN | c.1387C>A p.R463S (on ENST00000395871; = p.R415S on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs780959803, COSV100439882, COSV57014401; called by muse, mutect2
- POLR2G | c.13-1G>T p.X5_splice | Splice Site (SNP) | VAF 8/116 reads (7%) | catalogued as COSV100080197; called by muse, mutect2
- PON3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV55701828, COSV99672766; called by muse, mutect2
- PPM1E | c.1417C>A p.R473S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100376719, COSV57581395; called by muse, mutect2, varscan2
- PPP4R4 | c.624-1G>T p.X208_splice | Splice Site (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100429080; called by muse, mutect2
- PRDM7 | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100371388; called by muse, mutect2, varscan2
- PRICKLE1 | c.2441C>A p.T814K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.879); catalogued as COSV100454316; called by muse, mutect2, varscan2
- PRKDC | c.12178A>T p.T4060S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as COSV100043255; called by muse, mutect2
- PRKDC | c.10612G>A p.E3538K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.709); catalogued as rs1259477804, COSV100043258; called by muse, mutect2, varscan2
- PROKR1 | c.50C>A p.T17N | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100375767; called by muse, mutect2
- PROKR2 | c.1106C>A p.T369N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99450708; called by muse, varscan2
- PRRC2A | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100784640; called by muse, mutect2, varscan2
- PRRG3 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV100948713; called by mutect2, varscan2
- PRSS58 | c.281C>A p.S94* | Nonsense Mutation (SNP) | VAF 11/95 reads (12%) | catalogued as COSV101616172; called by muse, mutect2, varscan2
- PRUNE1 | c.974A>G p.K325R | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV99640012; called by muse, mutect2, varscan2
- PSD4 | c.1799G>A p.G600D | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99831517; called by muse, mutect2
- PSIP1 | c.1253T>A p.M418K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV101051015; called by muse, mutect2, varscan2
- PTDSS1 | c.949C>G p.H317D | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100428996; called by muse, mutect2, varscan2
- PTGDR | c.395T>G p.L132R | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100035763; called by muse, mutect2, varscan2
- PTPRN | c.167-1G>T p.X56_splice | Splice Site (SNP) | VAF 5/41 reads (12%) | catalogued as COSV55351681; called by muse, mutect2
- PXDNL | c.3004A>T p.R1002W | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100686777; called by muse, mutect2
- RAB38 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV99703416; called by muse, mutect2
- RASGEF1B | c.448A>G p.R150G | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV100021203; called by muse, mutect2, varscan2
- RASGEF1C | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.01); catalogued as rs376754942; called by mutect2, varscan2
- RB1CC1 | c.3025G>T p.D1009Y | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.44); catalogued as COSV99213128; called by muse, mutect2, varscan2
- RBFOX1 | c.931G>C p.G311R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100303870; called by muse, mutect2, varscan2
- RBPJL | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100643458, COSV100643552; called by mutect2, varscan2
- RELL2 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.056); catalogued as rs757296062, COSV99781371; called by muse, mutect2, varscan2
- RESF1 | c.698A>G p.K233R | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV100440679; called by muse, mutect2, varscan2
- RNASEH1 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100177297; called by muse, mutect2
- RNF17 | c.176G>T p.C59F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); catalogued as COSV99694585; called by muse, mutect2, varscan2
- RNF17 | c.3871T>C p.C1291R | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99694590; called by muse, mutect2, varscan2
- RP1 | c.3070T>A p.C1024S | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.053); catalogued as COSV99609038; called by muse, mutect2, varscan2
- RPTN | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100285860; called by muse, mutect2, varscan2
- RWDD2B | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as rs1215918774, COSV99725533; called by muse, mutect2
- RXYLT1 | c.593T>A p.V198D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99707132; called by muse, mutect2, varscan2
- SALL1 | c.1642C>G p.L548V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99192192; called by muse, mutect2, varscan2
- SALL1 | c.671T>A p.L224Q | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV99192193; called by muse, mutect2, varscan2
- SATB1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100113508; called by muse, mutect2, varscan2
- SCAMP5 | c.599T>A p.V200E | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV100723866; called by muse, mutect2
- SCAP | c.1855C>A p.P619T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.115); catalogued as rs1360899757, COSV99653319; called by muse, mutect2, varscan2
- SCGB1D2 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99793617; called by muse, mutect2, varscan2
- SCN2A | c.2330C>T p.A777V | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99333759; called by muse, mutect2
- SCN2A | c.5082G>T p.M1694I | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV99333763; called by muse, mutect2, varscan2
- SCN3A | c.1991C>A p.T664K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.343); catalogued as COSV99328757; called by muse, mutect2, varscan2
- SCN5A | c.1850A>T p.H617L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as rs974947142, COSV100350936; called by muse, mutect2
- SERPINA12 | c.443G>C p.R148P | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100369664, COSV100369775, COSV100369852; called by muse, mutect2
- SF3B2 | c.1344G>T p.K448N | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100488697; called by muse, mutect2
- SI | c.3755C>G p.P1252R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100017390; called by muse, mutect2
- SIDT1 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.181); catalogued as COSV99334855; called by muse, mutect2, varscan2
- SLC16A7 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99676925; called by muse, mutect2
- SLC17A3 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV100399434, COSV57759720; called by muse, mutect2, varscan2
- SLC35E4 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1479496417, COSV100299333; called by muse, mutect2, varscan2
- SLC6A18 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs764678224, COSV99722720; called by muse, mutect2, varscan2
- SLC7A3 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as COSV99979889; called by muse, mutect2, varscan2
- SLFN13 | c.1923-2A>T p.X641_splice | Splice Site (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99540467; called by muse, mutect2
- SLIT1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99822683; called by muse, mutect2, varscan2
- SLITRK2 | c.2374C>A p.R792S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as COSV100158281, COSV59423685, COSV59428874; called by muse, mutect2, varscan2
- SLITRK4 | c.1934G>T p.R645L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100567547, COSV62023284; called by muse, mutect2, varscan2
- SMCP | c.4T>A p.C2S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.085); catalogued as COSV100908370; called by muse, mutect2, varscan2
- SNTG2 | c.1246T>A p.F416I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100425156; called by muse, mutect2
- SNURF | c.61G>C p.V21L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.739); catalogued as COSV100578700; called by muse, mutect2, varscan2
- SNX14 | c.296A>G p.H99R | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100121820; called by muse, mutect2, varscan2
- SOX13 | c.1145G>T p.S382I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as COSV99690073; called by muse, mutect2, varscan2
- SOX30 | c.1895G>T p.S632I (on ENST00000265007 / NM_178424.2; = p.V468F on NM_007017.2) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99398824; called by muse, mutect2
- SPAG17 | c.1447C>A p.H483N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100310783; called by muse, mutect2, varscan2
- SPATA19 | c.357G>T p.W119C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100141292, COSV54483283; called by muse, mutect2, varscan2
- SPTA1 | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV63758639; called by muse, mutect2, varscan2
- STAU2 | c.695G>T p.G232V (on ENST00000524300 / NM_001164380.2; = p.G200V on NM_014393.2) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100869314; called by muse, mutect2
- STXBP1 | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1410513659, COSV100964645; called by muse, mutect2, varscan2
- STYK1 | c.37A>C p.S13R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV99312305; called by muse, mutect2, varscan2
- SULT1B1 | c.224T>A p.I75N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV100150350; called by muse, mutect2, varscan2
- SVEP1 | c.7057C>T p.H2353Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs928610170, COSV99929934; called by muse, mutect2, varscan2
- SYNE1 | c.18249G>T p.Q6083H (on ENST00000367255 / NM_182961.4; = p.Q6012H on NM_033071.3) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as rs748739828, COSV99581692; called by muse, mutect2, varscan2
- SYNE1 | c.12997A>C p.K4333Q (on ENST00000367255 / NM_182961.4; = p.K4262Q on NM_033071.3) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.061); catalogued as COSV99581698; called by muse, mutect2, varscan2
- SYNE1 | c.4384A>G p.I1462V (on ENST00000367255 / NM_182961.4; = p.I1469V on NM_033071.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); catalogued as COSV99581706; called by muse, mutect2, varscan2
- SYNJ2 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV100840683; called by muse, mutect2
- TAF1L | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs1039723762, COSV54270353, COSV99645557; called by muse, mutect2, varscan2
- TAF2 | c.139-2A>C p.X47_splice | Splice Site (SNP) | VAF 8/83 reads (10%) | catalogued as COSV100978826; called by muse, mutect2
- TDO2 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV101539810; called by muse, mutect2, varscan2
- TENM3 | c.3328A>T p.N1110Y | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV101305506; called by muse, mutect2, varscan2
- TENT5C | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs1476955055, COSV101033168; called by muse, mutect2, varscan2
- TET3 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV59880707; called by muse, mutect2
- TEX13A | c.539C>G p.A180G | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.53); catalogued as COSV100782132, COSV61161595; called by muse, mutect2, varscan2
- TF | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53920770, COSV99396489; called by muse, mutect2, varscan2
- TIGD2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.063); catalogued as COSV100392497; called by muse, mutect2, varscan2
- TIMP4 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.731); catalogued as COSV99826124; called by muse, mutect2, varscan2
- TLL1 | c.78G>C p.W26C | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV99289365; called by muse, mutect2, varscan2
- TMEM154 | c.365-1G>A p.X122_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100433226; called by muse, mutect2, varscan2
- TMEM71 | c.419C>G p.S140C (on ENST00000523829 / NM_001382398.1; = p.S121C on NM_144649.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100785715; called by muse, mutect2, varscan2
- TNR | c.2507C>A p.P836Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1341398869, COSV99691886; called by muse, mutect2, varscan2
- TNS4 | c.176G>T p.C59F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV54187889, COSV99564196; called by muse, mutect2, varscan2
- TPTE | c.1009C>A p.H337N (on ENST00000618007 / NM_199261.4; = p.H319N on NM_199259.4) | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1302442512; called by muse, mutect2
- TPTE | c.1631G>T p.S544I (on ENST00000618007 / NM_199261.4; = p.S526I on NM_199259.4) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.039); catalogued as rs1409385803; called by muse, mutect2, varscan2
- TRIM10 | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.492); catalogued as COSV100939874; called by muse, mutect2
- TRIM51 | c.1168A>C p.S390R | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.097); catalogued as rs756583153, COSV99793224; called by muse, mutect2, varscan2
- TRIM69 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV100274437; called by muse, mutect2, varscan2
- TRIM9 | c.1934C>A p.A645D | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.41); catalogued as COSV100032310; called by muse, mutect2, varscan2
- TRPA1 | c.1652C>G p.A551G | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as rs1335951070, COSV100085383, COSV51566522; called by muse, mutect2
- TSN | c.515C>G p.T172S | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV101067618; called by muse, mutect2
- TTN | c.51353C>G p.T17118S (on ENST00000591111; = p.T9694S on NM_003319.4) | Missense Mutation (SNP) | VAF 12/148 reads (8%) | PolyPhen benign (0.084); catalogued as COSV60404862; called by muse, mutect2
- TTN | c.45671G>T p.G15224V (on ENST00000591111; = p.G7800V on NM_003319.4) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | PolyPhen possibly damaging (0.56); catalogued as COSV100633083; called by muse, mutect2, varscan2
- TTN | c.32071G>C p.E10691Q (on ENST00000591111; = p.E9764Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | PolyPhen benign (0.347); catalogued as COSV100633086; called by muse, mutect2, varscan2
- TTN | c.6575C>T p.A2192V (on ENST00000591111; = p.A2146V on NM_003319.4) | Missense Mutation (SNP) | VAF 6/77 reads (8%) | PolyPhen benign (0.026); catalogued as COSV100633090; called by muse, mutect2
- TXK | c.541T>A p.L181I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV99972937; called by muse, mutect2, varscan2
- TXNRD1 | c.865A>T p.R289W (on ENST00000525566 / NM_001093771.3; = p.R191W on NM_003330.4) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100723601; called by muse, mutect2, varscan2
- UGGT1 | c.385G>C p.A129P | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99391284; called by muse, mutect2
- UNC5C | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as COSV101498056; called by muse, mutect2
- USH2A | c.8279A>G p.H2760R | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100243396; called by muse, mutect2, varscan2
- USP29 | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as COSV99518780; called by muse, mutect2, varscan2
- USP44 | c.62G>C p.S21T | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99312096; called by muse, mutect2
- UTP20 | c.5884T>C p.Y1962H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as COSV99882666; called by muse, mutect2, varscan2
- VPS13B | c.2437C>A p.Q813K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100663867; called by muse, mutect2, varscan2
- VWF | c.5322G>T p.L1774F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99780401; called by muse, mutect2, varscan2
- WAC | c.1645G>C p.A549P | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100611215; called by muse, mutect2
- WFIKKN2 | c.1206G>A p.W402* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100260135; called by muse, mutect2, varscan2
- XIRP1 | c.4643T>A p.L1548Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100454034; called by muse, mutect2, varscan2
- XIRP2 | c.2200G>T p.V734F (on ENST00000628543; = p.V909F on NM_152381.6) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99748177; called by muse, mutect2, varscan2
- XIRP2 | c.4198G>A p.D1400N (on ENST00000628543; = p.D1575N on NM_152381.6) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs374546171, COSV99748179; called by muse, mutect2, varscan2
- YOD1 | c.724C>G p.Q242E | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV100263309; called by muse, mutect2, varscan2
- YPEL3 | c.161T>C p.V54A (on ENST00000398838 / NM_001145524.2; = p.V92A on NM_031477.5) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as COSV99661823; called by muse, mutect2, varscan2
- ZC3H13 | c.1235G>C p.R412P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99669013; called by mutect2, varscan2
- ZC3H13 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99669014; called by muse, mutect2, varscan2
- ZFHX4 | c.4202A>T p.H1401L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV99268487; called by muse, mutect2, varscan2
- ZFP42 | c.600G>T p.R200S | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV100479200, COSV58819263; called by muse, mutect2, varscan2
- ZFP57 | c.984G>T p.R328S | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV100971985; called by muse, mutect2, varscan2
- ZIC3 | c.630C>G p.Y210* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99799615; called by muse, mutect2, varscan2
- ZNF155 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.179); catalogued as COSV99525820; called by muse, mutect2, varscan2
- ZNF317 | c.1060A>T p.R354W | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56108662, COSV99927387; called by muse, mutect2, varscan2
- ZNF460 | c.137G>T p.C46F | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV100828140; called by muse, mutect2
- ZNF470 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV100401423; called by muse, mutect2, varscan2
- ZNF48 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100198246, COSV60783064; called by muse, mutect2
- ZNF512B | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV99412972; called by muse, mutect2, varscan2
- ZNF583 | c.1047G>C p.E349D | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99382345; called by muse, mutect2, varscan2
- ZNF589 | c.367C>G p.P123A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100685836; called by muse, mutect2, varscan2
- ZNF611 | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV100160675; called by muse, mutect2, varscan2
- ZNF613 | c.1150A>G p.K384E (on ENST00000293471 / NM_001031721.4; = p.K348E on NM_024840.4) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV99523087; called by muse, mutect2, varscan2
- ZNF804B | c.1358C>A p.T453N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV60849909; called by muse, mutect2
- ZSCAN4 | c.1183C>A p.P395T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99990395; called by muse, mutect2, varscan2
- ACACA | c.4328G>A p.G1443E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK2 | c.11217_11218del p.Q3740Gfs*21 | Frame Shift Del (DEL) | VAF 16/166 reads (10%) | called by pindel, varscan2*
- BTN3A2 | c.792del p.G265Efs*13 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- CCDC50 | c.127del p.A43Hfs*25 | Frame Shift Del (DEL) | VAF 26/127 reads (20%) | called by mutect2, pindel, varscan2
- CCDC88A | c.3647A>G p.E1216G | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2
- CLMP | c.388+2T>A p.X130_splice | Splice Site (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- ENOX1 | c.1256A>T p.E419V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2
- FRG2C | c.335-2A>T p.X112_splice | Splice Site (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- GRIN2B | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.042); called by muse, mutect2
- GUCY1A1 | c.251C>A p.P84Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GXYLT1 | c.932del p.L311Qfs*11 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- H2AC4 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ITGAL | c.1997del p.R666Pfs*34 | Frame Shift Del (DEL) | VAF 9/88 reads (10%) | called by mutect2, varscan2
- LILRB3 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2
- MORC1 | c.1234C>T p.H412Y | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MRC1 | c.3799G>T p.G1267C | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MRGPRX2 | c.804dup p.S269Ifs*3 | Frame Shift Ins (INS) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- MUC17 | c.7399C>A p.P2467T | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2
- MYT1L | c.2537A>T p.Q846L | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2
- NLGN4X | c.381del p.W127Cfs*9 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | called by mutect2, pindel, varscan2
- NR6A1 | c.258del p.S87Afs*39 (on ENST00000487099 / NM_033334.4; = p.S83Afs*39 on NM_001489.5) | Frame Shift Del (DEL) | VAF 27/79 reads (34%) | called by mutect2, pindel, varscan2
- OR5T2 | c.33C>A p.N11K | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2
- PAPOLB | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB9 | c.1377C>A p.F459L | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- POTED | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by mutect2, varscan2
- PRAMEF12 | c.1430G>T p.C477F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- RADX | c.2214del p.K738Nfs*16 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- RALGAPA2 | c.982G>C p.D328H | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); called by muse, mutect2
- SLC4A1 | c.2389del p.V797Sfs*32 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | called by mutect2, pindel, varscan2
- SSTR1 | c.608A>T p.D203V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2
- TDRD6 | c.1427dup p.A477Sfs*21 | Frame Shift Ins (INS) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- TRBV2 | c.183A>T p.K61N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- TRIM44 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- USP48 | c.1780del p.V594Wfs*12 | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | called by mutect2, pindel
- XKR3 | c.1036C>A p.L346I | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZBTB43 | c.1049_1051del p.N350del | In Frame Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- ACSM1 | c.426C>T p.T142= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV54635147, COSV99533492; called by muse, mutect2
- ADARB2 | c.1908C>G p.P636= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV101184579; called by muse, mutect2, varscan2
- ARHGAP17 | c.2016C>A p.T672= (on ENST00000289968 / NM_001006634.3; = p.T594= on NM_018054.6) | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV99254147; called by muse, mutect2, varscan2
- ASPH | c.1971A>G p.T657= | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as COSV101064509; called by muse, mutect2
- ATP13A4 | c.2901C>A p.I967= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100710798; called by muse, mutect2
- ATP13A4 | c.135C>A p.I45= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV99795321; called by muse, mutect2, varscan2
- ATXN2 | c.2172T>A p.I724= (on ENST00000550104; = p.I564= on NM_002973.4) | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV101112920; called by muse, mutect2
- B4GALT6 | c.534G>T p.L178= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99380399; called by muse, mutect2, varscan2
- BFSP2 | c.138C>A p.A46= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV100183980; called by muse, mutect2
- CA2 | c.366C>T p.H122= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99570358; called by muse, mutect2, varscan2
- CCDC148 | c.423G>A p.Q141= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs1191204501, COSV99321621; called by muse, mutect2, varscan2
- CCDC171 | c.1278G>C p.S426= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs750679426, COSV99902192; called by muse, mutect2, varscan2
- CCL20 | c.151C>A p.R51= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100721899, COSV62591281; called by muse, mutect2, varscan2
- CCSER1 | c.1014G>C p.P338= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs370616330, COSV100396869; called by muse, mutect2, varscan2
- CCSER1 | c.1224A>G p.K408= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as rs1434901251, COSV61439941; called by muse, mutect2
- CDH11 | c.1845G>T p.L615= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV51773139, COSV99219979; called by muse, mutect2
- CDH19 | c.2241T>C p.Y747= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100052475; called by muse, mutect2, varscan2
- CIT | c.5976G>C p.R1992= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99951167; called by muse, mutect2, varscan2
- CPEB4 | c.654T>C p.F218= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV99437773; called by muse, mutect2
- CPNE8 | c.1197T>G p.A399= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100505201; called by muse, mutect2
- CRB1 | c.3345T>C p.G1115= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV100958094; called by muse, mutect2, varscan2
- CRTC1 | c.285C>T p.T95= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100119672; called by muse, mutect2
- CYP3A5 | c.282A>C p.L94= | Silent (SNP) | VAF 11/121 reads (9%) | catalogued as COSV99770159; called by muse, mutect2
- DCDC2 | c.138C>G p.V46= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV51239755; called by muse, mutect2, varscan2
- DNAJC1 | c.426C>T p.Y142= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100978058; called by muse, mutect2, varscan2
- DOK5 | c.555G>T p.R185= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99374943; called by muse, mutect2, varscan2
- DPYD | c.735T>A p.I245= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100929532; called by muse, mutect2, varscan2
- DYRK4 | c.114G>C p.A38= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- EEF1AKNMT | c.672G>A p.E224= (on ENST00000361735 / NM_015935.5; = p.E138= on NM_014955.3) | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs1246827372, COSV100676067; called by muse, mutect2
- EIF3E | c.1224C>A p.T408= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV99623601; called by muse, mutect2, varscan2
- EPHA3 | c.195C>T p.I65= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as rs1474534437, COSV100349296; called by muse, mutect2
- F13B | c.1959G>T p.L653= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV100803507; called by muse, mutect2, varscan2
- FAM135B | c.3666C>A p.I1222= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV99428254; called by muse, mutect2
- FAT4 | c.6414A>T p.T2138= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV100630425; called by muse, mutect2, varscan2
- FBXW7 | c.1254G>T p.V418= (on ENST00000281708 / NM_001349798.2; = p.V338= on NM_018315.5) | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as COSV55902403, COSV99661626; called by muse, mutect2, varscan2
- FGD2 | c.558C>A p.I186= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99236756; called by muse, mutect2, varscan2
- FIGN | c.264C>A p.L88= | Silent (SNP) | VAF 13/149 reads (9%) | catalogued as COSV100293024; called by muse, mutect2
- FMN2 | c.2241C>A p.S747= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs761871971, COSV100147489; called by muse, mutect2, varscan2
- GALNT15 | c.1857G>T p.P619= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100328044; called by muse, mutect2, varscan2
- GALNT17 | c.90C>G p.P30= | Silent (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- GATAD2A | c.1425G>C p.R475= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99390810; called by muse, mutect2, varscan2
- GBP3 | c.1743G>A p.L581= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV52520230; called by muse, mutect2
- GFM2 | c.1305T>A p.T435= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99714730; called by muse, mutect2, varscan2
- GLYR1 | c.582C>T p.A194= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as rs372325257; called by muse, mutect2, varscan2
- GNG13 | c.102G>A p.L34= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs950486041, COSV99243770; called by muse, mutect2, varscan2
- GPC2 | c.639C>A p.L213= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99445142; called by muse, mutect2
- GPR171 | c.309C>A p.I103= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV99854962; called by muse, mutect2
- GRID2 | c.1665A>T p.T555= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV99947628; called by muse, mutect2, varscan2
- GRIP1 | c.2883G>C p.R961= (on ENST00000359742 / NM_001379345.1; = p.R909= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV99671231; called by muse, mutect2, varscan2
- GRM3 | c.888C>A p.T296= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100862964; called by muse, mutect2, varscan2
- GRM5 | c.1881G>T p.L627= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100554798; called by muse, mutect2, varscan2
- GTF2IRD1 | c.780G>T p.T260= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV56091825; called by muse, mutect2
- HAVCR1 | c.210C>G p.T70= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100208640; called by muse, mutect2, varscan2
- HCN3 | c.1767C>T p.A589= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100713055; called by mutect2, varscan2
- HMCN1 | c.10737A>G p.G3579= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99636804; called by muse, mutect2, varscan2
- HTR3A | c.618G>A p.Q206= | Silent (SNP) | VAF 41/165 reads (25%) | catalogued as COSV100248673; called by muse, mutect2, varscan2
- IGKC | c.258C>A p.A86= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- IL22 | c.51C>A p.A17= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100048973; called by muse, mutect2
- IQCN | c.3081A>T p.T1027= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100828448; called by muse, mutect2, varscan2
- ISG15 | c.201C>A p.P67= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV101046169; called by muse, mutect2, varscan2
- JOSD1 | c.399G>A p.L133= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99320225; called by muse, mutect2, varscan2
- KCNC2 | c.1890T>C p.S630= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100130018; called by muse, mutect2
- KCTD8 | c.195C>G p.V65= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100760182; called by muse, mutect2
- KMT2E | c.1032A>G p.K344= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99997107; called by muse, mutect2, varscan2
- LAIR1 | c.114G>C p.V38= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV100479926; called by muse, mutect2, varscan2
- LAMP5 | c.688C>A p.R230= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99855728; called by muse, mutect2, varscan2
- LCE2C | c.54C>A p.P18= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV64228531; called by muse, mutect2
- LILRB3 | c.555C>G p.P185= | Silent (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- LIPH | c.276A>G p.V92= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs1450719457, COSV99956369; called by muse, mutect2
- LRFN3 | c.465C>A p.A155= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV99873652; called by muse, mutect2, varscan2
- LRP1B | c.9195C>A p.P3065= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV67195057; called by muse, mutect2, varscan2
- LRRC7 | c.3474G>A p.V1158= (on ENST00000651989 / NM_001370785.2; = p.V1125= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV99230209; called by muse, mutect2, varscan2
- LUC7L | c.738G>A p.R246= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs1319179284, COSV99551508; called by muse, mutect2, varscan2
- MAMDC2 | c.1206C>A p.P402= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV101015905; called by muse, mutect2, varscan2
- MARCHF11 | c.1005G>T p.R335= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV100198307; called by muse, mutect2, varscan2
- MGAT5B | c.1221C>A p.A407= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- MICU2 | c.636A>C p.T212= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV101212514; called by muse, mutect2
- MTERF2 | c.981A>T p.P327= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV53527278, COSV99527000; called by muse, mutect2, varscan2
- MTMR3 | c.3588T>A p.T1196= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as rs1284283662, COSV100071439; called by muse, mutect2
- MUC16 | c.39129G>T p.L13043= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs773226808, COSV101201947; called by muse, mutect2, varscan2
- MYCBP2 | c.4842C>A p.I1614= (on ENST00000357337; = p.I1652= on NM_015057.5) | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100632158; called by muse, mutect2
- MYH1 | c.462C>T p.H154= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as COSV99877044; called by muse, mutect2
- MYH13 | c.1125G>C p.A375= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV52824039, COSV99355704; called by mutect2, varscan2
- OPCML | c.822C>T p.N274= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100105600; called by muse, mutect2, varscan2
- OR10K2 | c.315C>A p.L105= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV100149683; called by muse, mutect2
- OR1G1 | c.762T>A p.T254= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100187618; called by muse, mutect2, varscan2
- OR2G3 | c.339C>T p.I113= | Silent (SNP) | VAF 29/160 reads (18%) | catalogued as rs267598475, COSV60680836; called by muse, mutect2, varscan2
- OR52N5 | c.378C>T p.L126= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV57699140; called by muse, mutect2, varscan2
- OR5D13 | c.369C>T p.D123= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as rs766341159, COSV62332929; called by muse, mutect2, varscan2
- OR5J2 | c.735G>A p.L245= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV100399289, COSV100399308; called by muse, mutect2, varscan2
- OR5M11 | c.90G>T p.L30= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV101602071; called by muse, mutect2, varscan2
- OR5W2 | c.543C>A p.I181= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV100747766, COSV60614817; called by muse, mutect2, varscan2
- OR8B2 | c.660C>T p.F220= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV66665200; called by muse, mutect2
- OR8H2 | c.36C>T p.D12= | Silent (SNP) | VAF 14/186 reads (8%) | catalogued as COSV100542497; called by muse, mutect2
- OR8J3 | c.522C>A p.I174= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV100040547, COSV56882411; called by muse, mutect2
- OR8K1 | c.210A>G p.R70= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as COSV99687572; called by muse, mutect2
- OR9A2 | c.648C>T p.Y216= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV100628294; called by muse, mutect2
- OSBPL9 | c.1248G>A p.L416= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100544147; called by muse, mutect2
- PAPPA2 | c.570G>A p.R190= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100867063, COSV62775454; called by muse, mutect2, varscan2
- PAPSS1 | c.426A>G p.A142= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99492489; called by muse, mutect2, varscan2
- PCDHA2 | c.1686G>A p.A562= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as rs527830690, COSV65366180; called by muse, mutect2, varscan2
- PCDHB12 | c.2265G>C p.V755= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV99507933; called by muse, mutect2, varscan2
- PCDHB2 | c.2040G>T p.P680= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as COSV99164145, COSV99166862; called by muse, mutect2, varscan2
- PCDHGB6 | c.1215G>T p.V405= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99548242; called by muse, mutect2, varscan2
- PDE1A | c.381T>A p.A127= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100116626; called by muse, mutect2, varscan2
- PI4KA | c.1623C>T p.T541= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99748924; called by muse, mutect2, varscan2
- PKHD1 | c.9C>A p.A3= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100584783; called by muse, mutect2, varscan2
- PLCB2 | c.642C>T p.S214= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs753790431, COSV99542754; called by mutect2, varscan2
- POLR2A | c.3987G>A p.K1329= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs764911266; called by muse, mutect2, varscan2
- PPIP5K2 | c.1539T>C p.G513= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100384324; called by muse, mutect2
- PREX2 | c.3945T>G p.G1315= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99910378; called by muse, mutect2, varscan2
- PTPRM | c.4227C>A p.L1409= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100160971, COSV59875488; called by muse, mutect2, varscan2
- PTPRM | c.4228C>A p.R1410= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100160974, COSV59874805; called by muse, mutect2, varscan2
- RAD23A | c.1065C>A p.L355= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100380514; called by muse, mutect2
- RAPH1 | c.576A>T p.S192= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV100052014; called by muse, mutect2
- ROS1 | c.4032C>T p.T1344= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1346010401, COSV100877775; called by muse, mutect2, varscan2
- RP1 | c.261G>A p.R87= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV55126457; called by muse, mutect2, varscan2
- RPL15 | c.303T>A p.V101= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100323296; called by muse, mutect2, varscan2
- S1PR1 | c.1059C>T p.S353= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100541711; called by muse, mutect2, varscan2
- SCAF4 | c.2481A>T p.S827= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99742215; called by muse, mutect2
- SCN11A | c.4767C>A p.I1589= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100182776, COSV56578307; called by muse, mutect2, varscan2
- SEMA3E | c.1182C>A p.T394= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV100319737; called by muse, mutect2, varscan2
- SEMG2 | c.1179T>G p.P393= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV101034254; called by muse, mutect2, varscan2
- SFMBT2 | c.2113A>C p.R705= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100739731; called by muse, mutect2, varscan2
- SLC18A3 | c.474C>A p.G158= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV60330653; called by muse, mutect2, varscan2
- SLC22A25 | c.609C>T p.R203= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- SLC43A1 | c.1215C>T p.S405= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV99561265; called by muse, mutect2, varscan2
- SMARCB1 | c.426C>T p.P142= (on ENST00000263121; = p.P188= on NM_003073.5) | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as CD110305, COSV99575827; called by muse, mutect2
- SNX8 | c.888G>T p.A296= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99771203; called by mutect2, varscan2
- SOWAHB | c.1260A>G p.E420= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100530804; called by muse, mutect2, varscan2
- ST6GAL2 | c.306C>A p.S102= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV64527611, COSV64530680; called by muse, mutect2, varscan2
- SYNPO2 | c.1455A>G p.P485= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1406297944, COSV100206498; called by muse, mutect2, varscan2
- SYT6 | c.318C>T p.L106= (on ENST00000610222 / NM_001366225.1; = p.L21= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV101059787; called by muse, mutect2, varscan2
- TAS2R1 | c.864A>G p.A288= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV101225884; called by muse, mutect2, varscan2
- TMC7 | c.1383G>T p.T461= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs147850292, COSV100432858; called by muse, mutect2, varscan2
- TNN | c.3468G>A p.A1156= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs369876797; called by mutect2, varscan2
- TPTE2 | c.585A>G p.R195= (on ENST00000400230 / NM_199254.2; = p.R118= on NM_130785.3) | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- TRAM1L1 | c.600T>A p.I200= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100162380; called by muse, mutect2, varscan2
- TRMT6 | c.1150C>T p.L384= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99177632; called by muse, mutect2, varscan2
- TRMT9B | c.261C>A p.A87= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV101501676; called by muse, mutect2, varscan2
- TSHZ3 | c.2604C>T p.I868= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs1453994376, COSV99552964; called by muse, mutect2, varscan2
- TTN | c.21642T>C p.S7214= (on ENST00000591111; = p.S6287= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/153 reads (5%) | catalogued as COSV100633087; called by muse, mutect2
- TXNDC5 | c.1086A>G p.E362= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99307511; called by mutect2, varscan2
- TYK2 | c.2760C>T p.N920= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV53389478; called by mutect2, varscan2
- UACA | c.2802G>T p.S934= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs756032048, COSV100537828, COSV59854129; called by muse, mutect2, varscan2
- UNC5C | c.2262G>A p.K754= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV101498055; called by muse, mutect2, varscan2
- UNC79 | c.7419C>T p.F2473= (on ENST00000393151 / NM_001346218.2; = p.F2296= on NM_020818.5) | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99830072; called by muse, mutect2, varscan2
- VIM | c.1092C>A p.R364= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV56405751, COSV99813392; called by muse, mutect2, varscan2
- VIM | c.1093C>T p.L365= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV99813393; called by muse, mutect2, varscan2
- ZAN | c.3748C>T p.L1250= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100770507; called by muse, mutect2, varscan2
- ZFHX4 | c.10479A>T p.S3493= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ZIC3 | c.1014C>A p.I338= | Silent (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2
- ZMAT4 | c.535T>C p.L179= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as COSV99911489; called by muse, mutect2
- ZMAT4 | c.441T>C p.C147= | Silent (SNP) | VAF 32/210 reads (15%) | catalogued as COSV99911492; called by muse, mutect2, varscan2
- ZMYND8 | c.216A>G p.P72= (on ENST00000311275 / NM_001363741.2; = p.P92= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV99521406; called by muse, mutect2, varscan2
- ZNF43 | c.2319A>G p.Q773= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as rs1237954298, COSV100731984; called by muse, mutect2
- ZNF521 | c.2622G>A p.G874= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100833538; called by muse, mutect2, varscan2
- ZNF615 | c.831A>T p.I277= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV100944017; called by muse, mutect2
- ZNF799 | c.1680T>C p.Y560= | Silent (SNP) | VAF 11/140 reads (8%) | catalogued as COSV101345302; called by muse, mutect2
- ALMS1P1 | chr2:73701058 G>C | 3'Flank (SNP) | VAF 8/68 reads (12%) | catalogued as rs376979668; called by muse, mutect2, varscan2
- C12orf77 | n.584T>C | RNA (SNP) | VAF 5/44 reads (11%) | catalogued as rs753647702; called by mutect2, varscan2
- C15orf54 | n.676T>C | RNA (SNP) | VAF 16/110 reads (15%) | catalogued as rs895529273; called by muse, mutect2, varscan2
- MIR1246 | n.9T>C | RNA (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- MTUS1 | c.2449+1784G>T | Intron (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100030156; called by muse, mutect2, varscan2
- NDUFV3 | c.170-5388C>G | Intron (SNP) | VAF 12/90 reads (13%) | catalogued as rs1232773600, COSV100447195; called by muse, mutect2, varscan2
- OR2W5 | n.480_481del | RNA (DEL) | VAF 6/52 reads (12%) | called by pindel, varscan2
- OR2W5 | n.1259G>A | RNA (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- RGS3 | c.3081-376G>C | Intron (SNP) | VAF 24/153 reads (16%) | catalogued as COSV100637081; called by muse, mutect2, varscan2
- SLC25A3 | c.282+198G>A | Intron (SNP) | VAF 4/70 reads (6%) | catalogued as COSV99499700; called by muse, mutect2
- SNORD115-19 | n.66G>A | RNA (SNP) | VAF 13/116 reads (11%) | catalogued as rs760341285; called by muse, mutect2, varscan2
- TMPRSS3 | c.-153C>A | 5'UTR (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99368766; called by muse, mutect2
- ZNF493 | c.-11G>T | 5'UTR (SNP) | VAF 13/102 reads (13%) | catalogued as COSV100828977; called by muse, mutect2, varscan2
